Somatic mutation profile of tumor specimen TCGA-D1-A0ZZ-01A (aliquot TCGA-D1-A0ZZ-01A-11D-A10M-09) from TCGA case TCGA-D1-A0ZZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 80.5 years (29,420 days).
Specimen TCGA-D1-A0ZZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0aad6d1e-deec-4794-800a-3407d523fd4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A0ZZ-10A (Blood Derived Normal), aliquot TCGA-D1-A0ZZ-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa6e1356-4579-43e9-a838-a76b871fde23

The open-access MAF lists 71 somatic variants for this specimen: 57 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 47, Silent 14, Nonsense Mutation 5, Frame Shift Del 2, In Frame Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.754_756del p.L252del | In Frame Del (DEL) | VAF 88/99 reads (89%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACSF2 | c.1549G>A p.G517S | Missense Mutation (SNP) | VAF 119/590 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51972866; called by muse, mutect2, varscan2
- AKAP6 | c.2467T>A p.L823M | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55216516; called by muse, mutect2, varscan2
- AMBRA1 | c.2012C>G p.S671* (on ENST00000458649 / NM_001367468.1; = p.S581* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV54055421; called by muse, varscan2
- AMBRA1 | c.1918C>T p.P640S (on ENST00000458649 / NM_001367468.1; = p.P550S on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV54055443; called by muse, varscan2
- AMBRA1 | c.1832C>A p.S611* (on ENST00000458649 / NM_001367468.1; = p.S521* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV54055462; called by muse, mutect2, varscan2
- APOB | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs148167725; called by muse, mutect2, varscan2
- ATP8B4 | c.2899T>A p.L967I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV52717046; called by muse, mutect2, varscan2
- B4GALNT3 | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774931975, COSV56753359; called by muse, mutect2, varscan2
- CDH8 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs771617779, COSV54865437; called by muse, mutect2, varscan2
- CFH | c.1120T>G p.C374G | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62777736; called by muse, mutect2, varscan2
- CFHR4 | c.1474C>A p.L492I (on ENST00000367416 / NM_001201551.2; = p.L246I on NM_006684.5) | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1261226694, COSV52230157; called by muse, mutect2
- CNOT8 | c.564C>G p.F188L | Missense Mutation (SNP) | VAF 130/223 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV53585725; called by muse, mutect2, varscan2
- COL16A1 | c.2059G>T p.A687S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.212); catalogued as COSV54707475; called by muse, mutect2, varscan2
- EPHB1 | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67662923; called by muse, mutect2, varscan2
- ERBB4 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484791833, COSV53499709, COSV53525659; called by muse, mutect2, varscan2
- FBXL12 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 49/386 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs199575681; called by muse, mutect2, varscan2
- FBXL12 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV56114336; called by muse, mutect2, varscan2
- FLNA | c.5586C>A p.Y1862* (on ENST00000369850 / NM_001110556.2; = p.Y1854* on NM_001456.3) | Nonsense Mutation (SNP) | VAF 165/183 reads (90%) | catalogued as COSV61044524; called by muse, mutect2, varscan2
- GK | c.379A>C p.S127R | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV66737134; called by muse, mutect2, varscan2
- GMIP | c.2686G>A p.E896K | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as rs1363796433, COSV52556950; called by muse, mutect2, varscan2
- HDAC5 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs756178431, COSV56819422; called by muse, mutect2, varscan2
- HPR | c.632C>G p.S211* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as COSV57183185; called by muse, mutect2, varscan2
- HYAL4 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56138870, COSV56140506; called by muse, mutect2, varscan2
- ILVBL | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as rs1396083505, COSV54620155; called by muse, mutect2, varscan2
- IPO8 | c.2422C>T p.H808Y | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.424); catalogued as COSV56241039, COSV56242004, COSV56242337; called by muse, mutect2, varscan2
- KCNH2 | c.2231G>A p.R744Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as rs1264176305, CD057242, CM121222, CM161523, COSV51141391; called by muse, mutect2, varscan2
- KIAA1109 | c.14919G>A p.M4973I | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52676829; called by muse, mutect2, varscan2
- MARCHF8 | c.870del p.H290Qfs*43 | Frame Shift Del (DEL) | VAF 53/169 reads (31%) | catalogued as COSV60572752; called by mutect2, pindel, varscan2
- MTREX | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1046909777, COSV57926680; called by muse, mutect2
- MYH2 | c.3373G>C p.E1125Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV55439936; called by muse, mutect2, varscan2
- MYOCD | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs778429833, COSV58505020; called by muse, mutect2, varscan2
- OR14A16 | c.748T>C p.S250P | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.917); catalogued as rs1375445196, COSV62926767; called by muse, mutect2, varscan2
- OR4K5 | c.474C>G p.S158R | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60003814; called by muse, mutect2, varscan2
- OR5D13 | c.273C>A p.Y91* | Nonsense Mutation (SNP) | VAF 20/105 reads (19%) | catalogued as COSV62333996; called by muse, mutect2, varscan2
- OR5M11 | c.814A>C p.I272L | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.363); catalogued as COSV73141851; called by muse, mutect2, varscan2
- PIEZO2 | c.6703G>T p.V2235L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs777624157, COSV53290477; called by muse, mutect2, varscan2
- PLEK | c.565T>A p.Y189N | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV52252232; called by muse, mutect2, varscan2
- REXO5 | c.777T>G p.D259E | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54472551; called by muse, mutect2, varscan2
- RNF111 | c.1007+2T>C p.X336_splice | Splice Site (SNP) | VAF 61/68 reads (90%) | catalogued as COSV62086665; called by muse, mutect2, varscan2
- RORA | c.1394G>T p.G465V (on ENST00000335670 / NM_134261.3; = p.G490V on NM_002943.3) | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV55040028; called by muse, mutect2, varscan2
- SAMSN1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs199748093, COSV53470841; called by muse, mutect2, varscan2
- SCN9A | c.2704G>T p.D902Y (on ENST00000303354; = p.D891Y on NM_002977.3) | Missense Mutation (SNP) | VAF 69/127 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57612471; called by muse, mutect2, varscan2
- SDK2 | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV66187661; called by muse, mutect2, varscan2
- SH3PXD2A | c.3241G>A p.A1081T (on ENST00000369774 / NM_001365079.1; = p.A1053T on NM_014631.2) | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1224789654, COSV60116490; called by muse, mutect2, varscan2
- SLC6A19 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs770356208, COSV58671837; called by muse, mutect2, varscan2
- SPATA18 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54645622; called by muse, mutect2
- STEAP3 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs748187004, COSV61529010; called by muse, mutect2, varscan2
- SYNCRIP | c.260A>G p.H87R | Missense Mutation (SNP) | VAF 187/432 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV62287984; called by muse, mutect2, varscan2
- TMEM67 | c.1768T>A p.F590I | Missense Mutation (SNP) | VAF 16/454 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60040552; called by muse, mutect2
- TPO | c.1358A>C p.Y453S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61103341; called by muse, mutect2, varscan2
- ZFYVE1 | c.1850A>T p.K617M | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59611452; called by muse, mutect2, varscan2
- ZNF180 | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as rs780505738, COSV55421736; called by muse, mutect2, varscan2
- ZNF507 | c.1912G>C p.E638Q | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV61331746; called by muse, mutect2
- ZNF610 | c.1305G>C p.K435N | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58345113; called by muse, mutect2, varscan2
- CCDC32 | c.517_534del p.E173_D178del | In Frame Del (DEL) | VAF 12/33 reads (36%) | called by pindel, varscan2
- FTO | c.6_27del p.K2_?9 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel
- DSCAM | c.5928A>C p.G1976= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV68028313; called by muse, mutect2, varscan2
- DVL3 | c.1611G>A p.P537= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as COSV53048490; called by muse, mutect2, varscan2
- FPR3 | c.702T>A p.I234= | Silent (SNP) | VAF 46/241 reads (19%) | catalogued as COSV59330268; called by muse, mutect2, varscan2
- GABRB1 | c.348C>G p.L116= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV54977790, COSV54984925; called by muse, mutect2, varscan2
- GPR143 | c.426T>C p.Y142= | Silent (SNP) | VAF 52/172 reads (30%) | catalogued as COSV66632621; called by muse, mutect2, varscan2
- HMCN1 | c.8052G>A p.V2684= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as COSV54906894; called by muse, mutect2, varscan2
- MYCBP2 | c.8854C>A p.R2952= (on ENST00000357337; = p.R2990= on NM_015057.5) | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV62022493, COSV62032185; called by muse, mutect2, varscan2
- MYO1G | c.402C>T p.V134= | Silent (SNP) | VAF 66/285 reads (23%) | catalogued as COSV51855032; called by muse, mutect2, varscan2
- PRPF39 | c.81T>C p.H27= | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as COSV63276959; called by muse, mutect2, varscan2
- SETBP1 | c.4065G>A p.V1355= | Silent (SNP) | VAF 41/270 reads (15%) | catalogued as COSV56324775; called by muse, mutect2, varscan2
- SIDT1 | c.1638C>T p.Y546= | Silent (SNP) | VAF 40/252 reads (16%) | catalogued as rs149502056; called by muse, mutect2, varscan2
- TSHZ3 | c.429G>A p.S143= | Silent (SNP) | VAF 78/334 reads (23%) | catalogued as rs757745397, COSV53673453; called by muse, varscan2
- UIMC1 | c.522C>T p.N174= | Silent (SNP) | VAF 68/102 reads (67%) | catalogued as rs749616728, COSV65893762; called by muse, mutect2, varscan2
- VGLL3 | c.534C>G p.T178= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV67353193; called by muse, varscan2
